TCGA case TCGA-42-2590 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Christiana Healthcare. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2724109f-7d5a-402c-a915-741e43c6f7f9

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 57 years; Vital status: Dead; Days to death: 317 days.

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 57.4 years (20,965 days); Year of diagnosis: 2009; Method of diagnosis: Cytology; FIGO stage: Stage IV; Tumor grade: G2; Prior treatment: No; Residual disease: R1.
   Pathology details: Residual tumor measurement: >20 mm.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Treatment intent type: Adjuvant; Days to treatment start: 31 days; Number of cycles: 5; Treatment dose: 12,100 mg; Treatment outcome: Treatment Ongoing; Prescribed dose: 1600; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 38 days; Number of cycles: 5; Treatment dose: 2,470 mg; Treatment outcome: Treatment Ongoing; Prescribed dose: 640; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel; Initial disease status: Progressive Disease; Days to treatment start: 249 days; Days to treatment end: 269 days; Number of cycles: 2; Treatment dose: 235 mg; Prescribed dose: 110; Prescribed dose units: mg; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Progression of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 58.0 years (21,191 days); Days to diagnosis: 226 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease.

Follow-up (4 entries)
- Day 226 (post initial treatment): Progression or recurrence: Yes; Days to progression: 226 days; Evidence of progression type: Convincing Image Source.
- Days to follow up: 227 days; Disease response: With Tumor.
- Days to follow up: 317 days; Disease response: With Tumor.
- ECOG performance status: 1; Timepoint: Prior to Adjuvant Therapy.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-42-2590-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 2.2; Intermediate dimension: 0.6; Shortest dimension: 0.4.
  Slide TCGA-42-2590-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20.
  Slide TCGA-42-2590-01A-01-BS1: Section location: Bottom; Percent tumor cells: 75; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 20; Percent stromal cells: 5.
- Sample TCGA-42-2590-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-42-2590-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Performance status timing: Pre-Adjuvant Therapy; Method initial path diagnosis: Cytology (e.g. Peritoneal or pleural fluid).
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 3: Regimen number: 02; Pharmaceutical therapy drug name: Taxotere.
- Follow-up form 2: Tumor status: With tumor; Performance status timing: Post-Adjuvant Therapy.

GDC annotations on this case (curator notes; quoted as recorded):
- Genotype mismatch (a sample-identity caveat) on aliquot TCGA-42-2590-01A-01R-1048-01: Pairwise comparisons of expression results between platforms HT_HG-U133A and AgilentG4502A_07 suggests that results from this aliquot were from a different patient and therefore these data have been removed.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 317 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 317 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 226 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-42-2590-01A-01D-1043-01): tumor purity 0.76, ploidy 1.98, whole-genome doublings 0.
